Gene-level copy-number profile of tumor specimen C3L-09223-01 from CPTAC case C3L-09223, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 81.2 years (29,650 days).
Specimen C3L-09223-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Head & Neck; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 99539629-6a3f-45af-9138-23fade321c4a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-09223-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,236 have no estimate.
https://portal.gdc.cancer.gov/files/ce16c55e-98be-4dd0-907b-0edfa5a17358

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 59; copy number 2: 14,395; copy number 3: 2,216; copy number 4: 32,121; copy number 5: 1,374; copy number 6: 5,982; copy number 7: 292; copy number 8: 575; copy number 9: 211; copy number 10: 978; copy number 11: 24; copy number 12: 85; copy number 13: 54; copy number 15: 1.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:128,673,681–128,677,005, 2 genes (within-gene range 0–2): Metazoa_SRP, POU5F1P6.
- chr5:16,853,994–16,902,641, 2 genes (within-gene range 0–4): RNA5SP179, RPS26P28.
- chr11:55,602,360–55,652,854, 3 genes: OR4C11, OR4P4, OR4S2.
- chr16:84,459,259–84,467,361, 1 gene (within-gene range 0–2): ATP2C2-AS1.
- chr16:84,495,599–84,497,495, 1 gene (within-gene range 0–2): AC022165.1.
- chr17:18,426,861–18,551,705, 11 genes (within-gene range 0–2): KRT17P2, KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,353 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:147,019,656–149,162,944, 81 genes, copy number 10 (broad region; genes not listed).
- chr1:149,606,334–164,357,364, 667 genes, copy number 10 (broad region; genes not listed).
- chr2:71,984,182–72,148,038, 2 genes, copy number 11: RPS20P10, CYP26B1.
- chr11:67,812,557–68,053,762, 18 genes, copy number 9 (within-gene range 8–9): ENPP7P7, AP003716.1, LINC02754, RNU6-46P, RPS3AP40, AC004923.1, AC004923.2, AC004923.3, OR7E1P, UNC93B1, ALDH3B1, AC004923.4, NDUFS8, MIR7113, MIR4691, TCIRG1, MIR6753, AP002807.1.
- chr11:69,371,463–70,075,469, 19 genes, copy number 9: AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P.
- chr11:70,467,856–71,252,577, 1 gene, copy number 10 (within-gene range 8–10): SHANK2.
- chr11:70,626,441–81,556,425, 286 genes, copy number 10–12 (within-gene range 8–12) (broad region; genes not listed).
- chr11:81,842,435–81,842,669, 1 gene, copy number 10: AP002802.2.
- chr11:110,355,130–110,407,613, 1 gene, copy number 10: LINC02732.
- chr14:42,362,983–44,911,863, 26 genes, copy number 12: AL442163.1, AL450442.1, AL442163.2, AL442163.3, YWHAQP1, AL163153.1, TUBBP3, HNRNPUP1, KRT8P2, AL358913.1, ARHGAP16P, LINC02307, EIF4BP1, AL109766.1, YWHAZP1, AL161752.1, LINC02277, FSCB, AL356022.1, LINC02302, DOCK11P1, AL049870.2, AL049870.1, RRAGAP1, C14orf28, AL049870.3.
- chr17:27,411,438–27,431,623, 2 genes, copy number 9: AC090615.1, TBC1D3P5.
- chr17:30,529,688–30,565,576, 6 genes, copy number 9–15: ALOX12P1, AC011840.3, AC011840.5, TBC1D29P, AC011840.4, AC011840.2.
- chr17:32,265,832–32,906,584, 29 genes, copy number 9: RHBDL3, AC026620.1, AC005899.4, C17orf75, AC005899.3, OOSP1P2, MIR632, ZNF207, AC005899.6, AC005899.7, AC005899.5, AC005899.8, AC005899.1, AC005899.2, PSMD11, Y_RNA, CDK5R1, MYO1D, AC079336.5, AC079336.7, AC079336.2, AC079336.1, AC079336.6, AC079336.4, AC079336.3, AC025211.1, Y_RNA, AC084809.1, AC084809.2.
- chr20:44,347,552–51,131,667, 214 genes, copy number 9–13 (within-gene range 4–13) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 59. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
